Surgical pathology report (de-identified scan), TCGA case TCGA-VV-A829, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site  John Wayne Cancer Center, specimen TCGA-VV-A829-01A (Primary Tumor).

[page 1 of 5]
Coll:
Recd:

ADDENDUM

Addendum #3 Entered:

Please see report from

The report states:

MGMT Methylation Assay
Result: Gene Methylation DETECTED

Consultant's report/outside laboratory's report is on file in the Pathology
Department and
in Medical Records. Copies also to be separately mailed and/or hand delivered to
the above
physician distribution list.

Addendum Signed signature on file

Addendum #2 Entered:

Report received from

PTEN IHC: 2+ staining (out of 3) in 50% of tumor cells

Addendum Signed signature on file

Addendum #1 Entered:

Reports received from

1P/19Q DELETION BY FISH

1p Deletion by FISH: Deleted A
19q Deletion by FISH: Deleted A

EGFR BY PCR AND FRAGMENT ANALYSIS

EGFR by PCR and Fragment Analysis: Not Detected

Addendum Signed signature on file

ICD-0-3

Oligoastrocytoma, grade III 9382/3
Site: CQCF: brain, supratentorial, NOS
C71.0

Path: brain, frontal lobe C71.1

/w
9/17/14

[page 2 of 5]
CLINICAL HISTORY

Brain tumor.

GROSS DESCRIPTION

1. Labeled "left frontal brain tumor": The specimen consists of a 0.6 x 0.6 x 0.1 cm pale pink glistening delicate piece of soft tissue. Touch preps are prepared and the specimen is submitted entirely for frozen section, 1FSA.

INTRAOPERATIVE CONSULTATION (FROZEN SECTION):

- Cellular neoplasm with calcifications.

INTRAOPERATIVE CONSULTATION (WITH CYTOLOGY EVALUATION):

- Fibrillary appearance present.

Frozen section diagnosis reported to

2. Labeled "left frontal brain tumor": The specimen consists of an intact egg shaped tumor with smooth borders, 5.0 x 4.0 x 3.0 cm. Cut sections show solid soft gray red appearance. Representative tissue to lab per surgeon request (protocol After overnight fixation, representative sections are submitted in

2A-D.

Additional sections of tumor subsequently embedded as 2E-2H.

3. Labeled "left frontal brain tumor, anterior-inferior margin": The specimen consists of a 0.2 x 0.2 x 0.1 cm pale pink delicate piece of soft tissue. Touch preps are prepared and the specimen is submitted entirely for frozen section, 3FSA.

INTRAOPERATIVE CONSULTATION (FROZEN SECTION):

- Cellular and atypical, consistent with neoplasm.

INTRAOPERATIVE CONSULTATION (WITH CYTOLOGY EVALUATION):

- Cellular and atypical, consistent with neoplasm.

Frozen section diagnosis reported to

4. Labeled "left frontal calcification tumor cyst wall": The specimen consists of a 0.4 x 0.2 x 0.1 cm aggregate of tan hard calcifications. The specimen is wrapped, submitted entirely in 4A after decalcification.

5. Labeled "left frontal brain tumor, anterior-inferior nodule for frozen section": The specimen consists of a single piece of tan red tissue that measures 2.7 x 2.1 x 0.6 cm. Representative sections are taken for frozen section diagnosis and touch imprint slides and all tissue is embedded as 5FSA and 5B.

INTRAOPERATIVE CONSULTATION (SMEAR/TOUCH PRFP CYTOLOGY):

- Atypical cells present.

[page 3 of 5]
Intraoperative report to

INTRAOPERATIVE CONSULTATION (FROZEN SECTION):
- Neoplastic tissue.

Frozen section diagnosis reported to

6. Labeled "left frontal brain tumor medial-superior resection margin, FS": The specimen consists of two pieces of tan tissue measuring 0.8 x 0.7 x 0.3 cm and 0.2 cm in diameter. The larger piece is bisected. Touch prep is prepared and all tissue taken for frozen section diagnosis, embedded as 6FSA.

INTRAOPERATIVE CONSULTATION (STAT CYTOLOGY EVALUATION):
- Atypical cells present.

Stat cytology reported to

INTRAOPERATIVE CONSULTATION (FROZEN SECTION):
- Positive for neoplasm.

Frozen section diagnosis reported to

7. Labeled "left frontal brain tumor, posterior margin biopsy, FS": The specimen consists of a small piece of tan tissue, 0.2 x 0.2 x 0.1 cm. Imprint slide is prepared and all tissue taken for frozen section diagnosis, embedded as 7FSA.

INTRAOPERATIVE CONSULTATION (STAT CYTOLOGY EVALUATION):
- Atypical cells present.

Stat cytology reported to

INTRAOPERATIVE CONSULTATION (FROZEN SECTION):
- Few atypical cells, indefinite.
- Defer diagnosis to complete evaluation.

Frozen section diagnosis reported to

MICROSCOPIC

Histologic sections show a glial neoplasm with low grade and high grade components. Each component represents approximately 50% of the tumor, which spans an estimated 7 cm. Some of the low grade component of the neoplasm shows features of oligodendroglioma with small round nuclei and perinuclear clearing. Substantial areas of the neoplasm represent high grade glioma with more angulated and hyperchromatic nuclei more characteristic of astrocytic features. Prominent areas of gemistocytic and mini-gemistocytic cytologic features are present. A few scattered mitotic figures are identified but are not numerous. Focal necrosis is noted but represents less than 5% of the neoplasm. Surgical margins are

[page 4 of 5]
positive including the final posterior margin (specimen #7) in which a few atypical cells are present within brain tissue and sufficient cytologically to qualify as focal involvement by the glial neoplasm.

IMMUNOCYTOCHEMISTRY RESULTS

Block 2B

GFAP: Diffusely positive
Ki-67: Intermediate (10-15%)
p53: No over-expression (5-10% of cells weakly stained)

Block 2C

GFAP: Diffusely positive
Ki-67: Intermediate (10-15%)
p53: No over-expression (5-10% of cells weakly stained)

Positive and negative controls demonstrate appropriate reactivity.

COMMENT

The slides have been reviewed by _____ and case findings discussed in _____. The findings are diagnostic of a high grade glial neoplasm arising in association with a lower grade glial neoplasm that demonstrates morphologic features consistent with oligodendroglioma. The differential diagnosis includes anaplastic oligo-astrocytoma with necrosis (favored diagnosis) and overt glioblastoma multiforme. The favored diagnosis is considered to be synonymous with GBM with oligodendroglial features. Molecular analysis for 1p:19q deletions is currently pending and may be of help in further defining the nature of this neoplasm. Prognostic marker studies have also been requested _____ and will be reported subsequently when received.

DIAGNOSIS

1. BRAIN, LEFT FRONTAL (TUMOR), BIOPSY:
- POSITIVE FOR GLIAL NEOPLASM (SEE BELOW).
2. BRAIN, LEFT FRONTAL (TUMOR), TUMOR TISSUE EXCISION:
- HIGH GRADE GLIOMA, FAVOR ANAPLASTIC OLIGOASTROCYTOMA WITH NECROSIS (WHO GRADE 3).
- PLEASE SEE COMMENT.
3. BRAIN, LEFT FRONTAL (TUMOR), ANTERIOR-INFERIOR MARGIN EXCISION:
- POSITIVE FOR GLIAL NEOPLASM, HIGH GRADE.
4. BRAIN, LEFT FRONTAL (CALCIFICATION TUMOR CYST WALL), BIOPSY:
- CALCIFIED TISSUE, CONSISTENT WITH CALCIFIED COMPONENT OF GLIAL NEOPLASM.
5. BRAIN, LEFT FRONTAL (TUMOR), ANTERIOR-INFERIOR NODULE BIOPSY:
- HIGH GRADE GLIAL NEOPLASM.
6. BRAIN, LEFT FRONTAL (TUMOR), MEDIAL-SUPERIOR RESECTION MARGIN BIOPSY:

[page 5 of 5]
POSITIVE FOR GLIAL NEOPLASM.

7. BRAIN, LEFT FRONTAL (TUMOR), POSTERIOR MARGIN BIOPSY:
- FEW ATYPICAL CELLS, CONSISTENT WITH EDGE OF GLIAL NEOPLASM.

CENTRAL NERVOUS SYSTEM TUMOR SYNOPTIC REPORT

TUMOR SITE:	LEFT FRONTAL
LATERALITY:	LEFT
HISTOLOGIC TYPE:	FAVOR OLIGOASTROCYTOMA
HISTOLOGIC GRADE (WHO):	HIGH GRADE (3/4)
ANCILLARY STUDIES:	IN PROGRESS

signed Electronically signed by:

** END OF REPORT **

Criteria	hw 10/1/13	Yes	No

Source: NCI Genomic Data Commons file 991d421c-c53f-42fb-804e-fe08fbea9a49 (TCGA-VV-A829.CD914F13-6DA0-47EE-90AD-DD2C3F2A727B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).